Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3AB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3AB-06A (Metastatic).

[page 1 of 2]
REPORT COPY

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Enquiries

REQUESTING DR :
VERIFIED BY :

SPECIMEN DATE :
ACCESSION :

REPORTED BY

Reported by: Dr

Previous Lab. Ref:

CLINICAL INFORMATION

M30. Metastatic melanoma.

100-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary C 77.3

hw 9/21/11

OPERATION/NATURE OF SPEC

Large axillary mass (right side).

MACROSCOPIC DESCRIPTION

"Right axillary contents". An irregular skin ellipse 100 x 53mm with a large amount of attached subcutaneous fat and muscle. In the fat is a large tumour mass. The tumour appears grossly encapsulated and has a firm pale cut surface. The tumour was previously opened prior to receipt and a central portion of it appears to have already been removed. The specimen is 95 x 90 x 75mm. This mass is located in the fat and abuts skeletal muscle. A scar is present on the skin, 50mm in length. The remainder of the specimen was examined for lymph nodes.

- A. Representative section of large tumour mass.
B. 1 node.
C. 1 node in 3 pieces.
D. 1 node.
E. 1 node in 2 pieces.
F. 1 node in 2 pieces.
G. 1 node.
H. 1 node trisected.
J. 1 node.
K. 1 node.
L. 1 node bisected.
M. 3 nodes.
N. 4 nodes.
O. 1 node bisected.
P. 4 nodes.
Q. 1 node bisected.
R. 3 nodes.
S. 4 nodes.
T. 3 nodes.

A region of ? fat necrosis was found in the subcutaneous tissue underlying the scar.

* Continued next page *

[page 2 of 2]
REPORT COPY

DEPARTMENT OF ANATOMICAL PATHOLOGY

Professor

Enquiries

REQUESTING DR :

Verified by :

SPECIMEN DATE :

ACCESSION

MACROSCOPIC DESCRIPTION ...Cont'd

U. Skin and underlying ?fat necrosis.

U-W. Further blocks of tumour looking for extranodal extension

MICROSCOPIC DESCRIPTION

The (R) axillary dissection shows metastatic malignant melanoma forming a large presumably-node-based mass lesion. The melanoma has an epithelioid cytomorphology, no pigment and stains strongly for S100. (HMB45-, AE1/AE3-) Mitotic rate is 15/mm². There is a capsule around the tumour deposit, with no obvious percolation into fat, (but given its size I would be reluctant to consider that there is no extranodal extension).

The other uninvolved nodes (33 in number) show reactive hyperplasia, sinus oedema and some pigment in the sinuses. There is an overlying healing surgical scar with some fat necrosis.

DIAGNOSIS

(R) axillary dissection - Metastatic MALIGNANT MELANOMA (1/34).

SNOMED CODES

Axillary lymph node - Malignant melanoma, metastatic

- Skin resection

M-87206 P-01R T-08710

***** END OF ACCESSION *****

Source: NCI Genomic Data Commons file 8e2b7039-589b-4cf8-a4c0-cf0561ca0716 (TCGA-EE-A3AB.0782D02E-4CD6-4031-B62B-41E1C408E4BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).